Somatic mutation profile of tumor specimen 01d1ffca-4235-4dfe-bf62-56f71d (aliquot 01d1ffca-4235-4dfe-bf62-56f71d_D6_1) from CPTAC case 11CO032, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 01d1ffca-4235-4dfe-bf62-56f71d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45c5b830-d1e4-4507-b355-91523dffaf7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7a8f4f4f-c503-46f3-8239-e717ba (Blood Derived Normal), aliquot 7a8f4f4f-c503-46f3-8239-e717ba_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c239ea35-a8ab-4237-bb54-4f22b01adb01

The open-access MAF lists 105 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Intron 6, Nonsense Mutation 4, Frame Shift Ins 3, RNA 3, 3'UTR 3, Frame Shift Del 2, Splice Region 2, 5'Flank 2, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3901dup p.T1301Nfs*14 | Frame Shift Ins (INS) | VAF 176/408 reads (43%) | catalogued as rs1554085382, CI972537, COSV57348827; ClinVar: pathogenic; called by mutect2, varscan2
- MLH1 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 33/165 reads (20%) | catalogued as rs63749818, CM054778, CM1210016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 39/162 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 112/359 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3934G>A p.A1312T | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs779493132, COSV57057215; called by muse, mutect2
- ACACB | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200591816; called by muse, mutect2, varscan2
- ADCK1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs140603078; called by muse, mutect2
- APLN | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1240173234, COSV56742527; called by muse, mutect2, varscan2
- ATP1A2 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 102/460 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV63401929; called by muse, mutect2, varscan2
- CCDC154 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs998380269; called by muse, mutect2, varscan2
- CHAMP1 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs781891231; called by muse, mutect2, varscan2
- COL27A1 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs370579896; called by muse, mutect2, varscan2
- EDNRB | c.295G>A p.G99R (on ENST00000377211 / NM_001201397.1; = p.G9R on NM_000115.5) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV100526552; called by muse, varscan2
- ELOA2 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs774453041, COSV55301700; called by muse, mutect2, varscan2
- FAM184A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs906728986; called by muse, mutect2
- FBXL7 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 112/496 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1356248686, COSV61641264; called by muse, mutect2, varscan2
- GALNT9 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs782365948; called by muse, mutect2, varscan2
- GCGR | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1240225006; called by muse, mutect2
- HDAC9 | c.2632C>T p.L878F | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs776333855; called by muse, mutect2, varscan2
- INTS4 | c.1999C>G p.Q667E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV71090709; called by muse, mutect2, varscan2
- MEDAG | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs752208437; called by muse, mutect2, varscan2
- MTMR8 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 110/245 reads (45%) | catalogued as rs748650576, COSV66392772; called by muse, mutect2, varscan2
- OR4K5 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV60003136; called by muse, mutect2
- OTOG | c.5744G>T p.R1915L | Missense Mutation (SNP) | VAF 19/678 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV61131830; called by muse, mutect2
- PAMR1 | c.2021C>T p.P674L (on ENST00000619888 / NM_001001991.3; = p.P691L on NM_015430.4) | Missense Mutation (SNP) | VAF 134/585 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs201029324, COSV53512693; called by muse, mutect2, varscan2
- PLXNA2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 139/594 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as rs946385859, COSV65440431; called by muse, mutect2, varscan2
- PTGER3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60689789; called by muse, mutect2, varscan2
- PTPRS | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260947679, COSV53610215; called by muse, mutect2, varscan2
- PTPRT | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs751972373, COSV61965149; called by muse, mutect2, varscan2
- RACK1 | c.282G>A p.T94= | Splice Region (SNP) | VAF 45/196 reads (23%) | catalogued as rs758636714; called by muse, mutect2, varscan2
- SACS | c.7990G>A p.G2664R | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66538530; called by muse, mutect2, varscan2
- SEMA3D | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV52391487; called by muse, mutect2, varscan2
- SHANK2 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 140/640 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs782708379; called by mutect2, varscan2
- SHOC1 | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs746953682; called by muse, mutect2, varscan2
- SIN3A | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100845242; called by muse, mutect2, varscan2
- SMAD4 | c.1302T>A p.Y434* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV61693153, COSV61696863; called by muse, mutect2, varscan2
- TSC2 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 197/770 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs587781774, CD052519; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TTN | c.29990T>C p.I9997T (on ENST00000591111; = p.I9070T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/274 reads (18%) | PolyPhen benign (0.127); catalogued as rs886055288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPP2 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99135030; called by muse, mutect2, varscan2
- VTA1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs557156156; called by muse, mutect2, varscan2
- WDR27 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs550761168, COSV61211605; called by muse, mutect2, varscan2
- BCL9 | c.1611dup p.I538Yfs*35 | Frame Shift Ins (INS) | VAF 87/431 reads (20%) | called by mutect2, pindel, varscan2
- C1QL2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- CALN1 | c.267T>A p.D89E (on ENST00000329008 / NM_001017440.3; = p.D131E on NM_031468.4) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYP1A2 | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DEDD2 | c.287A>C p.H96P | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- DPP7 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPB41L4B | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPB42 | c.1225T>C p.S409P (on ENST00000441366 / NM_001114134.2; = p.S439P on NM_000119.3) | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- F12 | c.87T>G p.H29Q | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2
- FRY | c.6953G>T p.S2318I | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GMPS | c.1439del p.H480Lfs*19 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- HPSE2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL32 | c.1861T>G p.*621Gext*6 | Nonstop Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- MASTL | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- MLPH | c.545T>A p.F182Y | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MROH1 | c.3429-5T>C | Splice Region (SNP) | VAF 53/242 reads (22%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2894C>A p.A965E | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NMUR2 | c.350T>A p.V117E | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- NSMAF | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OMA1 | c.646del p.V216* | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | called by mutect2, pindel, varscan2
- OR2G2 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PDE10A | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLIN4 | c.1705G>C p.V569L (on ENST00000301286; = p.V584L on NM_001367868.2) | Missense Mutation (SNP) | VAF 118/573 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PPP1R3F | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2
- RAB3GAP2 | c.1873C>T p.L625F | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- RGL1 | c.1664G>A p.S555N (on ENST00000360851 / NM_001297672.2; = p.S590N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPS6KC1 | c.171dup p.K58* | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.3671G>A p.G1224E | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SRF | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF672 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 16/439 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- ZNF746 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF746 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 106/391 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABCC2 | c.3135T>C p.S1045= | Silent (SNP) | VAF 48/664 reads (7%) | called by muse, mutect2
- CD93 | c.330G>A p.P110= | Silent (SNP) | VAF 58/288 reads (20%) | catalogued as COSV55666342, COSV55666974; called by muse, mutect2, varscan2
- COL6A3 | c.2196G>A p.T732= | Silent (SNP) | VAF 181/784 reads (23%) | catalogued as rs768242367, COSV99796468, COSV99802057; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.5139G>A p.T1713= | Silent (SNP) | VAF 53/211 reads (25%) | catalogued as rs758984750, COSV60950355; called by muse, mutect2, varscan2
- EZR | c.369G>A p.V123= | Silent (SNP) | VAF 30/502 reads (6%) | called by muse, mutect2
- GRAMD1B | c.618A>G p.E206= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.3615C>T p.H1205= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as rs780089713; called by muse, mutect2
- MRGPRX3 | c.783C>T p.S261= | Silent (SNP) | VAF 82/388 reads (21%) | catalogued as rs780641792, COSV101283517; called by muse, mutect2, varscan2
- MYH9 | c.3159G>T p.L1053= | Silent (SNP) | VAF 93/289 reads (32%) | catalogued as rs201951100; called by muse, mutect2, varscan2
- NALCN | c.1191C>T p.D397= | Silent (SNP) | VAF 60/368 reads (16%) | catalogued as rs1450096508; called by muse, mutect2, varscan2
- NMNAT2 | c.552G>A p.T184= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs750949491; called by muse, mutect2, varscan2
- PAPPA2 | c.333G>A p.L111= | Silent (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- PCDHB6 | c.1182C>T p.S394= | Silent (SNP) | VAF 112/433 reads (26%) | catalogued as rs201246980, COSV50700397; called by muse, mutect2, varscan2
- PHACTR1 | c.1215C>T p.D405= | Silent (SNP) | VAF 80/292 reads (27%) | catalogued as rs774700729; called by muse, varscan2
- PODXL2 | c.75G>A p.A25= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs369628001; called by muse, mutect2, varscan2
- RIPOR2 | c.2616G>T p.L872= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- TXLNB | c.1881G>A p.E627= | Silent (SNP) | VAF 30/155 reads (19%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500786 A>G | 5'Flank (SNP) | VAF 34/125 reads (27%) | catalogued as rs749520381; called by muse, mutect2, varscan2
- C10orf88B | n.440G>T | RNA (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.401+16_401+23del | Intron (DEL) | VAF 36/184 reads (20%) | called by mutect2, pindel, varscan2
- DNM1L | c.-1C>T | 5'UTR (SNP) | VAF 21/105 reads (20%) | catalogued as rs151285821; called by muse, mutect2, varscan2
- EYS | c.1766+2567A>T | Intron (SNP) | VAF 12/188 reads (6%) | catalogued as COSV60984572; called by muse, mutect2
- FAM135B | c.157+1849A>C | Intron (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- KIAA1755 | c.2169+10G>A | Intron (SNP) | VAF 15/87 reads (17%) | catalogued as rs370164526; called by muse, mutect2, varscan2
- KLC1 | c.*10178C>A | 3'UTR (SNP) | VAF 46/139 reads (33%) | catalogued as rs1294025463; called by muse, mutect2, varscan2
- METTL26 | c.*7C>T | 3'UTR (SNP) | VAF 157/626 reads (25%) | catalogued as rs202129648; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.562C>T | RNA (SNP) | VAF 68/330 reads (21%) | catalogued as rs202060553; called by muse, mutect2, varscan2
- MOGAT3 | chr7:101202153 G>T | 5'Flank (SNP) | VAF 30/96 reads (31%) | catalogued as rs1465560507; called by muse, mutect2, varscan2
- NCF1B | n.304G>A | RNA (SNP) | VAF 67/589 reads (11%) | catalogued as rs782515046; called by muse, mutect2, varscan2
- NDUFA4L2 | c.*10G>A | 3'UTR (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- OSBPL6 | c.987+4536G>A | Intron (SNP) | VAF 32/102 reads (31%) | catalogued as rs765688279; called by muse, mutect2, varscan2
- TTLL9 | c.706-148G>A | Intron (SNP) | VAF 62/326 reads (19%) | catalogued as rs546119339; called by muse, mutect2, varscan2
